CCDI case PBCFZS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a3c81dc0-2a02-4e4f-9487-d314621b6f51

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (546 days).

Biospecimens (3 samples)
- Sample 0DR3L6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR3LZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR3MF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
